Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3848, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3848-01A (Primary Tumor).

Diagnosis:

This is an invasive adenocarcinoma of the colon (G2 – sigmoid colon) with infiltration of all parietal layers (pT3) with vascular infiltration L1, V1, with free resection margins and six lymph node metastases (6 of 12).

Tumor classification:

ICDO-DA M

G2

pT3, L1, V1, locally R0, pN2 (6 of 12)

Source: NCI Genomic Data Commons file 2101d82f-da36-41fa-bdd3-4833febece92 (TCGA-AA-3848.F8DDA0F2-1A9B-4219-BCFB-A33416AD74BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).